Gene-level copy-number profile of tumor specimen TCGA-09-0365-01A from TCGA case TCGA-09-0365, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.4 years (25,703 days).
Specimen TCGA-09-0365-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a176e8f9-e8b2-4133-bed2-2a7d63e5d2e6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-0365-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f3e96502-1bb4-4473-ada1-36d9c8776abd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 10; copy number 2: 6,086; copy number 3: 10,225; copy number 4: 18,722; copy number 5: 13,288; copy number 6: 5,481; copy number 7: 5,512; copy number 8: 260; copy number 9: 17; copy number 10: 73; copy number 14: 47; copy number 16: 14; copy number 17: 17; copy number 22: 35; copy number 26: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-09-0365-01A-02D-0356-01): tumor purity 0.94, ploidy 4.38, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 227 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:22,419,444–29,013,367, 155 genes, copy number 10–26 (within-gene range 6–26) (broad region; genes not listed).
- chr7:31,202,831–32,428,131, 8 genes, copy number 10 (within-gene range 5–10): AC006398.1, AC006380.1, NEUROD6, AC005090.1, ITPRID1, PPP1R17, PDE1C, SNX2P2.
- chr16:3,930,806–4,882,401, 47 genes, copy number 14 (within-gene range 7–14): LINC02861, ADCY9, AC005736.1, AC009171.1, AC009171.2, SRL, LINC01569, TFAP4, GLIS2, GLIS2-AS1, PAM16, AC012676.1, CORO7-PAM16, AC012676.5, CORO7, VASN, DNAJA3, AC012676.3, AC012676.4, AC012676.2, NMRAL1, HMOX2, CDIP1, AC023830.3, C16orf96, AC023830.2, SUB1P3, UBALD1, MGRN1, RN7SL850P, AC023830.1, Metazoa_SRP, MIR6769A, NUDT16L1, ANKS3, AC020663.1, C16orf71, ZNF500, Metazoa_SRP, SEPTIN12, AC020663.4, SMIM22, AC020663.2, ROGDI, GLYR1, AC020663.3, UBN1.
- chr16:9,104,848–9,113,181, 1 gene, copy number 9 (within-gene range 7–9): AC087190.3.
- chr16:9,156,402–10,227,581, 16 genes, copy number 9: RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195, AC007221.1, RNA5SP403, RNA5SP404, AC007218.1, GRIN2A, AC007218.2, AC007218.3, AC133565.1, IMPDH1P11, AC022168.1, RN7SL493P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
